Gene-level copy-number profile of tumor specimen CDDP-ABJO-TTP1-G from CDDP_EAGLE case CDDP-ABJO, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 54 years.
Specimen CDDP-ABJO-TTP1-G: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 38ccca2a-f3d4-48c0-b3d6-b5167bee684e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABJO-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/77dc329e-9fd3-4f47-b756-925707cc1f5a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,739; copy number 2: 49,211; copy number 3: 1,747; copy number 4: 1,462; copy number 5: 493; copy number 6: 233; copy number 8: 30.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 756 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,258,885–147,517,875, 1 gene, copy number 6 (within-gene range 4–6): LINC00624.
- chr1:147,419,053–154,502,412, 360 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr1:211,442,274–213,794,587, 56 genes, copy number 5: ARPC3P2, RD3, AC105275.1, SLC30A1, AC105275.2, AL356310.1, LINC01693, NEK2, FDPSP8, AC096637.2, AC096637.1, LPGAT1, RN7SL344P, Y_RNA, LPGAT1-AS1, AC092814.2, INTS7, AC092814.1, DTL, RPL21P28, MIR3122, RN7SKP98, AL606468.1, LINC02608, PPP2R5A, AL360091.2, AL360091.3, RPL23AP18, SNORA16B, AL360091.1, PACC1, NENF, LINC02771, LINC01740, AC092803.1, AC092803.4, ATF3, AL590648.2, FAM71A, AL590648.1, LINC02773, BATF3, NSL1, TATDN3, AC104333.3, SPATA45, FLVCR1-DT, AC104333.1, AC104333.2, FLVCR1, VASH2, ANGEL2, RPS6KC1, RPL31P13, AL592402.1, AC096639.1.
- chr1:223,393,415–224,162,047, 16 genes, copy number 5: CCDC185, CAPN8, SNRPEP10, RNU6-1248P, CAPN2, TP53BP2, PHBP11, ACTBP11, CICP5, GTF2IP20, RNU6-1319P, AC138393.1, AC138393.3, AC138393.2, RN7SKP49, FBXO28.
- chr19:34,533,427–38,208,369, 201 genes, copy number 5 (broad region; genes not listed).
- chr19:54,351,384–55,932,336, 122 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,885. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
